Somatic mutation profile of tumor specimen C3N-00389-04 (aliquot CPT0026270009) from CPTAC case C3N-00389, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.8 years (22,951 days).
Specimen C3N-00389-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74528a9f-b43d-4bdd-af29-166732abb877.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00389-71 (Blood Derived Normal), aliquot CPT0026370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9a84ca3-8e18-43f2-b655-5108d2d5886d

The open-access MAF lists 899 somatic variants for this specimen: 605 protein-altering or splice-affecting, 169 silent, 125 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 374, Silent 169, Frame Shift Del 132, Intron 61, Frame Shift Ins 38, Nonsense Mutation 24, 3'UTR 23, Splice Region 17, Splice Site 15, RNA 13, 5'UTR 10, 5'Flank 10.

Variants (750 of 899; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8432del p.K2811Sfs*46 | Frame Shift Del (DEL) | VAF 69/112 reads (62%) | catalogued as rs587782558; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- DSCAML1 | c.1411G>A p.V471I (on ENST00000321322; = p.V411I on NM_020693.4) | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0.013); catalogued as rs759222737, CM1512498, COSV58388948; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EIF2AK4 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587777106, CM140018; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 98/276 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 104/163 reads (64%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 60/228 reads (26%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NEK1 | c.1908del p.V637Cfs*34 | Frame Shift Del (DEL) | VAF 28/95 reads (29%) | catalogued as rs775849720; ClinVar: likely pathogenic; called by mutect2, varscan2
- PAX3 | c.879dup p.F294Vfs*116 | Frame Shift Ins (INS) | VAF 83/266 reads (31%) | catalogued as rs1553572967; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 44/133 reads (33%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- ABCA13 | c.8956-1G>A p.X2986_splice | Splice Site (SNP) | VAF 30/110 reads (27%) | catalogued as rs745315360; called by muse, varscan2
- ABCA9 | c.3498dup p.G1167Wfs*19 | Frame Shift Ins (INS) | VAF 31/124 reads (25%) | catalogued as rs1177267466; called by mutect2, pindel, varscan2
- ABCC10 | c.1465C>T p.R489W (on ENST00000372530 / NM_001198934.2; = p.R446W on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472560845; called by muse, mutect2, varscan2
- ABCC11 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 48/141 reads (34%) | catalogued as rs543285690, COSV62326005; called by muse, mutect2, varscan2
- ABHD13 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs768141867; called by muse, mutect2, varscan2
- ACAN | c.1505G>T p.R502L | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as rs144835580, COSV61360708; called by muse, mutect2, varscan2
- ACSS3 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778280883, COSV54083909; called by muse, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADCY8 | c.3298G>A p.V1100I | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751510726, COSV53920343; called by muse, mutect2
- AHDC1 | c.4120G>A p.E1374K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs765921462; called by muse, mutect2, varscan2
- ALAS2 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759169409, COSV100238087, COSV58189524; called by muse, mutect2, varscan2
- ANKS6 | c.2518del p.E840Rfs*66 | Frame Shift Del (DEL) | VAF 49/214 reads (23%) | catalogued as COSV62052120; called by mutect2, pindel, varscan2
- ANO1 | c.2102del p.P701Lfs*7 | Frame Shift Del (DEL) | VAF 63/233 reads (27%) | catalogued as rs1565270546, COSV60286460; called by mutect2, pindel, varscan2
- APC | c.2687C>T p.A896V | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs864622255; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP36 | c.-145G>A | Splice Region (SNP) | VAF 10/31 reads (32%) | catalogued as rs1024165725, COSV99357667; called by muse, mutect2, varscan2
- ARHGEF39 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs533238908; called by muse, mutect2, varscan2
- ARID1A | c.1280del p.P427Rfs*6 | Frame Shift Del (DEL) | VAF 94/373 reads (25%) | catalogued as COSV61382650; called by mutect2, pindel, varscan2
- ARL5C | c.107+3_107+6del | Splice Region (DEL) | VAF 46/140 reads (33%) | catalogued as rs1292718123; called by mutect2, pindel, varscan2
- ARMCX5-GPRASP2 | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 28/105 reads (27%) | catalogued as COSV63437861; called by muse, mutect2, varscan2
- ARSJ | c.1736dup p.K580Efs*32 | Frame Shift Ins (INS) | VAF 17/90 reads (19%) | catalogued as rs753865255; called by mutect2, varscan2
- ATP11A | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs754791463; called by muse, mutect2, varscan2
- ATP2B1 | c.3355C>T p.R1119* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as COSV53806099; called by muse, varscan2
- B4GAT1 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.427); catalogued as COSV60819768; called by muse, mutect2, varscan2
- BAZ2B | c.3131G>A p.R1044H | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs780427087; called by muse, mutect2, varscan2
- BCCIP | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758295476; called by muse, mutect2, varscan2
- BCL7C | c.617del p.P206Hfs*36 | Frame Shift Del (DEL) | VAF 28/90 reads (31%) | catalogued as rs754078059; called by mutect2, varscan2
- BMP1 | c.2321C>T p.T774M | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs750695022; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BPIFB4 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs143050216; called by muse, mutect2, varscan2
- BRINP2 | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs554141063; called by muse, mutect2, varscan2
- BTRC | c.1780del p.R594Vfs*14 (on ENST00000370187 / NM_033637.4; = p.R558Vfs*14 on NM_003939.5) | Frame Shift Del (DEL) | VAF 27/97 reads (28%) | catalogued as rs774921343; called by mutect2, pindel, varscan2
- C16orf70 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.251); catalogued as rs759714222; called by muse, mutect2, varscan2
- C1GALT1C1L | c.132C>A p.H44Q | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs760174670; called by muse, mutect2, varscan2
- C1QL2 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs781569526; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 33/124 reads (27%) | catalogued as rs750339990; called by mutect2, pindel, varscan2
- C8A | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63483756; called by muse, mutect2, varscan2
- CABS1 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as rs139939232; called by muse, mutect2, varscan2
- CACNA1F | c.3679A>G p.M1227V | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.342); catalogued as COSV59902887; called by muse, mutect2, varscan2
- CAPN10 | c.191A>G p.Q64R | Missense Mutation (SNP) | VAF 63/208 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as rs1369654441; called by muse, mutect2, varscan2
- CARNS1 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs751106258, COSV57052797; called by muse, mutect2, varscan2
- CBL | c.2692A>G p.I898V | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.017); catalogued as rs397507499, COSV50633325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBR4 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0.129); catalogued as COSV100085724; called by muse, mutect2, varscan2
- CCDC130 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746627348, COSV55584514; called by muse, mutect2, varscan2
- CCDC180 | c.4614del p.K1539Nfs*17 | Frame Shift Del (DEL) | VAF 31/92 reads (34%) | catalogued as rs1423532083; called by mutect2, pindel, varscan2
- CCDC184 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.623); catalogued as rs1321721435; called by muse, mutect2, varscan2
- CD1A | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as rs200592984, COSV56862534; called by muse, mutect2, varscan2
- CDH15 | c.1537dup p.H513Pfs*144 | Frame Shift Ins (INS) | VAF 40/184 reads (22%) | catalogued as rs763850576; called by mutect2, varscan2
- CDH23 | c.4729C>T p.R1577C | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs893684931, COSV56473725; called by muse, mutect2, varscan2
- CHD4 | c.2335C>T p.R779W (on ENST00000357008 / NM_001363606.2; = p.R792W on NM_001273.5) | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58901404; called by muse, mutect2, varscan2
- CHST11 | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 90/303 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.268); catalogued as COSV57985583; called by muse, mutect2, varscan2
- CLSTN2 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.248); catalogued as rs372613467; called by muse, mutect2, varscan2
- CNGA4 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 119/345 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV66006361; called by muse, mutect2, varscan2
- COIL | c.991T>C p.S331P | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs779492048; called by muse, mutect2, varscan2
- COL12A1 | c.4924del p.E1642Sfs*5 | Frame Shift Del (DEL) | VAF 39/150 reads (26%) | catalogued as COSV59390565; called by mutect2, pindel, varscan2
- COL15A1 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 102/347 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs764674198; called by muse, mutect2, varscan2
- CRAMP1 | c.2951T>G p.L984R | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1413754602; called by muse, mutect2, varscan2
- CSF3 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs368530987; called by muse, mutect2, varscan2
- CSTF2 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 152/438 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.572); catalogued as rs767318301, COSV65893688; called by muse, mutect2, varscan2
- CSTF3 | c.613del p.M205* | Frame Shift Del (DEL) | VAF 25/79 reads (32%) | catalogued as rs1300471016; called by mutect2, varscan2
- CTNS | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 150/546 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs768600706, COSV99251714; called by muse, mutect2, varscan2
- CTU2 | c.1075T>G p.S359A | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs772769195; called by muse, mutect2, varscan2
- DDX20 | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1008477588; called by muse, mutect2
- DENND4C | c.966dup p.E323* | Frame Shift Ins (INS) | VAF 38/140 reads (27%) | catalogued as rs1428440687; called by mutect2, varscan2
- DIAPH2 | c.2378G>A p.R793H | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1474480416; called by muse, mutect2
- DMAC1 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as rs1177257301, COSV64066097; called by muse, mutect2
- DMKN | c.*2T>C | Splice Site (SNP) | VAF 44/161 reads (27%) | catalogued as rs757655167; called by muse, mutect2, varscan2
- DNAH1 | c.7046G>A p.G2349D | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs965707978; called by muse, mutect2, varscan2
- DNAH8 | c.12067C>T p.R4023C | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs569195029, COSV59464938; called by muse, mutect2, varscan2
- DNAJC13 | c.6384C>T p.A2128= | Splice Region (SNP) | VAF 28/78 reads (36%) | catalogued as rs149354507; called by muse, varscan2
- DNAJC5B | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs772285428, COSV52537926; called by muse, mutect2
- DOCK8 | c.3637G>A p.A1213T | Missense Mutation (SNP) | VAF 76/305 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs1172637555, COSV101209763; called by muse, mutect2, varscan2
- DOP1B | c.5176C>T p.L1726F | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1377459581; called by muse, mutect2, varscan2
- DPH1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV53983930; called by muse, mutect2, varscan2
- DUS3L | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV57832307; called by muse, mutect2, varscan2
- E4F1 | c.1903G>A p.V635M | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs372658146; called by muse, mutect2, varscan2
- EEF1A2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV99035645; called by muse, mutect2, varscan2
- EFCAB12 | c.1162C>A p.R388S | Missense Mutation (SNP) | VAF 100/338 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs578026955; called by muse, mutect2, varscan2
- EFHC1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs200191497, CM125702; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 25/66 reads (38%) | catalogued as rs768793415; called by mutect2, varscan2
- EVX2 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs1559102548; called by muse, mutect2, varscan2
- FAM135A | c.1870G>A p.D624N (on ENST00000370479 / NM_001351599.1; = p.D411N on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs753865006; called by muse, mutect2, varscan2
- FAT4 | c.4942G>A p.V1648M | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749029819; called by muse, mutect2, varscan2
- FBN2 | c.8599A>G p.T2867A | Missense Mutation (SNP) | VAF 95/348 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV52516652; called by muse, mutect2, varscan2
- FCGBP | c.7252C>T p.R2418W | Missense Mutation (SNP) | VAF 58/430 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs1185597137; called by muse, mutect2, varscan2
- FCSK | c.2332C>T p.R778W | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs201319740; called by muse, mutect2, varscan2
- FLT4 | c.2167+2T>C p.X723_splice | Splice Site (SNP) | VAF 47/143 reads (33%) | catalogued as COSV56107612; called by muse, mutect2, varscan2
- FOXA1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 67/302 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs917539237; called by muse, mutect2, varscan2
- FOXO4 | c.574del p.R192Afs*83 | Frame Shift Del (DEL) | VAF 43/142 reads (30%) | catalogued as COSV58574664; called by mutect2, pindel, varscan2
- FREM1 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs763640629, COSV101085289; called by muse, mutect2, varscan2
- FRYL | c.1641-1G>A p.X547_splice | Splice Site (SNP) | VAF 35/149 reads (23%) | catalogued as COSV99977365; called by muse, mutect2, varscan2
- FUBP1 | c.30del p.S11Lfs*43 | Frame Shift Del (DEL) | VAF 55/104 reads (53%) | catalogued as rs908264837; called by mutect2, pindel, varscan2
- GAA | c.1396del p.V466Ffs*11 | Frame Shift Del (DEL) | VAF 36/120 reads (30%) | catalogued as COSV100163305; called by mutect2, pindel, varscan2
- GABRR1 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.863); catalogued as rs769296616; called by muse, mutect2, varscan2
- GABRR2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs769090430; called by muse, mutect2, varscan2
- GATD1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs376824470; called by muse, mutect2, varscan2
- GK | c.1462G>A p.V488I (on ENST00000427190 / NM_001205019.2; = p.V482I on NM_000167.6) | Missense Mutation (SNP) | VAF 166/532 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs768478671, COSV66732332; called by muse, mutect2, varscan2
- GLI1 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760192848, COSV99954799; called by muse, mutect2, varscan2
- GNL2 | c.53G>A p.S18N | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100894962; called by muse, mutect2, varscan2
- GPR37L1 | c.311dup p.N105Qfs*96 | Frame Shift Ins (INS) | VAF 103/345 reads (30%) | catalogued as rs1345944074; called by mutect2, pindel, varscan2
- GRB10 | c.1771C>T p.R591* (on ENST00000398812; = p.R545* on NM_001001549.3) | Nonsense Mutation (SNP) | VAF 76/240 reads (32%) | catalogued as rs775842626, COSV60013275; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs754199513; called by mutect2, varscan2
- GSPT2 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV61214362; called by muse, mutect2, varscan2
- GTPBP2 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.029); catalogued as rs769230699; called by muse, mutect2, varscan2
- HDAC4 | c.2758A>G p.S920G | Missense Mutation (SNP) | VAF 123/420 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs368612479; called by muse, mutect2, varscan2
- HELZ2 | c.6638dup p.P2214Sfs*34 (on ENST00000467148 / NM_001037335.2; = p.P1645Sfs*34 on NM_033405.3) | Frame Shift Ins (INS) | VAF 14/47 reads (30%) | catalogued as rs1336825230; called by mutect2, pindel, varscan2
- HIC1 | c.1112del p.P371Rfs*82 (on ENST00000322941 / NM_001098202.1; = p.P352Rfs*82 on NM_006497.4) | Frame Shift Del (DEL) | VAF 13/82 reads (16%) | catalogued as rs1567557055; called by mutect2, pindel, varscan2
- HMCN2 | c.15085C>T p.R5029C | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1554979063; called by muse, mutect2, varscan2
- IDH3G | c.775C>T p.Q259* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as rs1557069355; called by muse, mutect2, varscan2
- ING1 | c.1134G>A p.W378* | Nonsense Mutation (SNP) | VAF 39/126 reads (31%) | catalogued as COSV58168762, COSV58171881; called by muse, mutect2, varscan2
- INPP4B | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.392); catalogued as rs1477397139; called by muse, mutect2
- INSR | c.4028G>A p.R1343Q | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.331); catalogued as rs753624268, COSV100253760; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IQGAP2 | c.4213C>T p.R1405* | Nonsense Mutation (SNP) | VAF 24/87 reads (28%) | catalogued as rs750847318, COSV57168753, COSV99166818; called by muse, varscan2
- IRX2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 75/242 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs913850746; called by muse, mutect2, varscan2
- ISM1 | c.579del p.R194Gfs*82 | Frame Shift Del (DEL) | VAF 60/201 reads (30%) | catalogued as rs762230866, COSV99339624; called by mutect2, varscan2
- ITPKB | c.619del p.E207Sfs*24 | Frame Shift Del (DEL) | VAF 75/278 reads (27%) | catalogued as COSV99685374; called by mutect2, pindel, varscan2
- JAG2 | c.2220del p.G741Afs*21 | Frame Shift Del (DEL) | VAF 75/254 reads (30%) | catalogued as rs1555369773; called by mutect2, pindel, varscan2
- KANK3 | c.2251C>T p.Q751* | Nonsense Mutation (SNP) | VAF 57/194 reads (29%) | catalogued as rs1254975637; called by muse, mutect2, varscan2
- KCNJ3 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99715462; called by muse, mutect2, varscan2
- KDM2B | c.3379G>A p.V1127I | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1349703563; called by muse, mutect2, varscan2
- KIF2A | c.561C>T p.D187= | Splice Region (SNP) | VAF 11/51 reads (22%) | catalogued as rs1330714767; called by muse, mutect2, varscan2
- KIT | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 128/446 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144369407, CM149982, COSV55392159; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL30 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs867807772; called by muse, mutect2, varscan2
- KMT2A | c.10756G>A p.A3586T | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1555048868; called by muse, mutect2, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 35/153 reads (23%) | catalogued as COSV55868319; called by mutect2, pindel, varscan2
- LAMB2 | c.3904C>T p.R1302* | Nonsense Mutation (SNP) | VAF 145/474 reads (31%) | catalogued as rs756680527, COSV59739176; called by muse, mutect2, varscan2
- LARGE1 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 86/320 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.131); catalogued as rs374774937, COSV61674885; called by muse, mutect2, varscan2
- LGI3 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 118/368 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as rs752250633, COSV60443890; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 56/192 reads (29%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 60/239 reads (25%) | catalogued as rs748712732; called by mutect2, varscan2
- LPAR3 | c.40dup p.Y14Lfs*2 | Frame Shift Ins (INS) | VAF 25/66 reads (38%) | catalogued as rs767032705; called by mutect2, varscan2
- LRRK1 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.307); catalogued as rs554667646, COSV52609368; called by muse, mutect2, varscan2
- LRRTM2 | c.657G>T p.K219N | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99217760; called by muse, mutect2, varscan2
- LSM3 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as rs1015903438, COSV53203463; called by muse, mutect2, varscan2
- MAN2A1 | c.1916del p.N639Ifs*2 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as rs758700583; called by mutect2, varscan2
- MAPK15 | c.1538del p.G513Vfs*? | Frame Shift Del (DEL) | VAF 28/120 reads (23%) | catalogued as rs782558070; called by mutect2, pindel, varscan2
- MAST3 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1398236958, COSV99446170; called by muse, mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs746267361; called by mutect2, varscan2
- ME3 | c.1648A>G p.I550V | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs774252348; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | catalogued as rs762115034; called by mutect2, varscan2
- MGAT3 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.244); catalogued as rs747893252, COSV100361829; called by muse, mutect2, varscan2
- MISP | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs200094406; called by muse, mutect2, varscan2
- MLH1 | c.1496G>T p.R499M | Missense Mutation (SNP) | VAF 97/356 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV51622055; called by muse, mutect2, varscan2
- MLLT1 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV53129070; called by muse, mutect2, varscan2
- MMP8 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs138678979, COSV52631883; called by muse, mutect2
- MPHOSPH9 | c.1223C>A p.P408Q | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs755669070, COSV56622290; called by muse, mutect2, varscan2
- MROH7 | c.1389+1G>A p.X463_splice | Splice Site (SNP) | VAF 27/79 reads (34%) | catalogued as rs1196566332, COSV100273738; called by muse, mutect2, varscan2
- MUC6 | c.6815G>A p.R2272Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs767718878, COSV70146917; called by muse, mutect2, varscan2
- MYBBP1A | c.3685A>G p.T1229A | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749623968, COSV54605530; called by muse, mutect2, varscan2
- MYH11 | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 64/280 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466960409; called by muse, mutect2, varscan2
- MYO16 | c.2607dup p.L870Tfs*45 | Frame Shift Ins (INS) | VAF 38/152 reads (25%) | catalogued as rs1566464398; called by mutect2, varscan2
- MYO1H | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as rs761781333; called by muse, varscan2
- NAP1L3 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59077466; called by muse, mutect2, varscan2
- NAT10 | c.2698C>T p.R900C | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as rs375005009; called by muse, mutect2, varscan2
- NCKAP1 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.133); catalogued as rs1460725983, COSV62943712; called by muse, mutect2, varscan2
- NEMP2 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370283521, COSV58109455; called by muse, mutect2, varscan2
- NEUROD2 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.081); catalogued as rs1313064946; called by muse, mutect2, varscan2
- NLE1 | c.632A>G p.H211R | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62605137; called by muse, mutect2, varscan2
- NLRP2 | c.3113del p.N1038Tfs*4 | Frame Shift Del (DEL) | VAF 93/335 reads (28%) | catalogued as rs745782532; called by mutect2, pindel, varscan2
- NLRX1 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs775689434, COSV52703240; called by muse, mutect2, varscan2
- NOTCH3 | c.4585G>A p.A1529T | Missense Mutation (SNP) | VAF 65/235 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV54653049; called by muse, mutect2, varscan2
- NOTCH4 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs1304701623, COSV66681126; called by muse, mutect2
- NPVF | c.189del p.D64Ifs*10 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | catalogued as COSV56060641; called by mutect2, pindel
- NRTN | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 98/324 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.14); catalogued as rs1242064325; called by muse, mutect2, varscan2
- NUDCD1 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs765531808; called by muse, mutect2, varscan2
- OGFOD1 | c.421A>G p.M141V | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs202059284, COSV60200143; called by muse, mutect2, varscan2
- OLFM2 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199729659; called by muse, mutect2, varscan2
- OLR1 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1389033534; called by muse, mutect2, varscan2
- OR8B4 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.01); catalogued as rs765733880, COSV62069502; called by muse, mutect2, varscan2
- OTUD7B | c.161del p.P54Hfs*98 | Frame Shift Del (DEL) | VAF 40/142 reads (28%) | catalogued as COSV64916305; called by mutect2, pindel, varscan2
- OXER1 | c.231del p.S78Pfs*64 | Frame Shift Del (DEL) | VAF 54/190 reads (28%) | catalogued as rs753912794; called by mutect2, pindel, varscan2
- P2RX7 | c.532del p.R178Gfs*5 | Frame Shift Del (DEL) | VAF 53/167 reads (32%) | catalogued as rs1326587970; called by mutect2, pindel, varscan2
- P4HB | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769747717, COSV58943365; called by muse, mutect2, varscan2
- PAQR4 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs925884510, COSV51891346; called by muse, mutect2, varscan2
- PCDH11X | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 106/355 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1451020542, COSV100016238; called by muse, mutect2, varscan2
- PCDHA1 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 188/635 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.298); catalogued as COSV65377014; called by muse, mutect2, varscan2
- PCDHA6 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 71/307 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV65349232; called by muse, mutect2, varscan2
- PCDHB16 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 120/458 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs782190498; called by mutect2, varscan2
- PEAR1 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1331859933, COSV52771404, COSV52775330; called by muse, mutect2, varscan2
- PHTF1 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 95/324 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.498); catalogued as rs768596937; called by muse, varscan2
- PIK3C2B | c.4354G>A p.G1452S | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs757025537; called by muse, mutect2, varscan2
- PITPNM3 | c.2423_2425del p.F808del | In Frame Del (DEL) | VAF 82/268 reads (31%) | catalogued as rs754410582; called by pindel, varscan2
- PLCG2 | c.1122G>A p.W374* | Nonsense Mutation (SNP) | VAF 38/166 reads (23%) | catalogued as COSV63875206; called by muse, mutect2, varscan2
- PLCL2 | c.2185C>T p.R729W (on ENST00000615277 / NM_001144382.2; = p.R603W on NM_015184.5) | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67624553; called by muse, mutect2, varscan2
- PLXNA3 | c.49del p.A17Pfs*12 | Frame Shift Del (DEL) | VAF 39/144 reads (27%) | catalogued as rs782247826; called by mutect2, varscan2
- POFUT2 | c.1143del p.F381Lfs*101 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as COSV100499227; called by mutect2, pindel
- POM121L12 | c.369del p.L124Cfs*14 | Frame Shift Del (DEL) | VAF 60/217 reads (28%) | catalogued as rs765688315, COSV68693949; called by mutect2, pindel, varscan2
- PPM1D | c.1349del p.L450* | Frame Shift Del (DEL) | VAF 47/137 reads (34%) | catalogued as rs758630849; called by mutect2, pindel, varscan2
- PPP6R2 | c.2561del p.P854Rfs*23 (on ENST00000216061 / NM_001365836.1; = p.P820Rfs*23 on NM_014678.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 24/87 reads (28%) | catalogued as COSV53291064; called by mutect2, pindel, varscan2
- PRF1 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 86/267 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as COSV64615620; called by muse, mutect2, varscan2
- PRICKLE3 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 74/207 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as rs1473490379; called by muse, mutect2, varscan2
- PRPF8 | c.4355C>T p.P1452L | Missense Mutation (SNP) | VAF 112/378 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59268102; called by muse, mutect2, varscan2
- PRSS8 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs754311704, COSV99571233; called by muse, mutect2, varscan2
- PSMC4 | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs760361475; called by muse, mutect2, varscan2
- PTEN | c.365T>A p.I122N | Missense Mutation (SNP) | VAF 135/444 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as CM1513160, COSV64295127, COSV64309969; called by muse, mutect2, varscan2
- PTGER3 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs1170326123; called by muse, mutect2, varscan2
- PTGFR | c.97dup p.S33Ffs*27 | Frame Shift Ins (INS) | VAF 32/116 reads (28%) | catalogued as rs756672341; called by mutect2, varscan2
- RBM25 | c.2116G>A p.V706I | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.421); catalogued as rs369541790; called by muse, mutect2, varscan2
- REM1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 94/286 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52429824; called by muse, mutect2, varscan2
- REPIN1 | c.1116del p.S373Pfs*242 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs759247453; called by mutect2, varscan2
- RING1 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1465723110; called by muse, mutect2, varscan2
- RNASEH1 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.908); catalogued as rs1451703236; called by muse, mutect2, varscan2
- RNF10 | c.2388dup p.Q797Tfs*98 | Frame Shift Ins (INS) | VAF 34/108 reads (31%) | catalogued as rs991722425; called by mutect2, varscan2
- RNF112 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71978965; called by muse, mutect2, varscan2
- RNF220 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 81/268 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs377270177; called by muse, mutect2, varscan2
- SALL3 | c.2441C>T p.A814V | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs773984731, COSV73305806; called by muse, mutect2, varscan2
- SALL3 | c.3544A>G p.M1182V | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as rs779112698, COSV73306721; called by muse, mutect2, varscan2
- SAMD15 | c.1876G>A p.G626S | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs267604065, COSV53630632; called by muse, mutect2, varscan2
- SEC11C | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs375344740; called by muse, mutect2, varscan2
- SEC16B | c.2437G>A p.V813M | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs371826824; called by muse, mutect2, varscan2
- SEC24C | c.2266C>T p.R756W | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59539537; called by muse, mutect2, varscan2
- SERPINB12 | c.308T>C p.L103S | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1384458481; called by muse, mutect2, varscan2
- SH3PXD2A | c.2102G>C p.C701S (on ENST00000369774 / NM_001365079.1; = p.C673S on NM_014631.2) | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs779374922; called by muse, mutect2, varscan2
- SH3PXD2A | c.328dup p.H110Pfs*6 | Frame Shift Ins (INS) | VAF 16/68 reads (24%) | catalogued as rs777796332; called by mutect2, varscan2
- SHANK2 | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175797564; called by muse, mutect2
- SHB | c.750del p.F250Lfs*29 | Frame Shift Del (DEL) | VAF 38/152 reads (25%) | catalogued as COSV66621774; called by mutect2, pindel, varscan2
- SHC1 | c.92del p.P31Rfs*35 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | catalogued as rs752843778; called by mutect2, pindel, varscan2
- SHOX | c.728del p.P243Rfs*164 | Frame Shift Del (DEL) | VAF 75/342 reads (22%) | catalogued as rs757845999, COSV61860885; called by mutect2, pindel, varscan2
- SLC25A45 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99587247; called by muse, mutect2
- SLC45A4 | c.353G>A p.R118H (on ENST00000517878 / NM_001286646.2; = p.R67H on NM_001080431.2) | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226939655, COSV50132918; called by muse, mutect2, varscan2
- SLC52A2 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs782396304, COSV57353388; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLITRK4 | c.206A>T p.N69I | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62025880; called by muse, mutect2, varscan2
- SNAI3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.057); catalogued as rs200533581; called by muse, mutect2, varscan2
- SNTG2 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs954775834; called by mutect2, varscan2
- SPATA20 | c.484G>A p.G162R (on ENST00000356488 / NM_001258372.1; = p.G178R on NM_022827.4) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201429533, COSV50066038, COSV50068104; called by muse, mutect2, varscan2
- SPOCD1 | c.3282del p.R1095Gfs*32 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as rs1455579753; called by mutect2, pindel, varscan2
- STK11IP | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.871); catalogued as rs533235446; called by muse, mutect2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 42/154 reads (27%) | catalogued as rs770033147; called by mutect2, varscan2
- SYT17 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 79/220 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs374172730; called by muse, mutect2, varscan2
- TBX10 | c.291del p.F98Sfs*3 | Frame Shift Del (DEL) | VAF 75/266 reads (28%) | catalogued as rs748952707, COSV56876494; called by mutect2, pindel, varscan2
- TCIRG1 | c.2182G>A p.V728I | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs145723719; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 21/74 reads (28%) | catalogued as rs763321097; called by mutect2, varscan2
- TEKT5 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 96/308 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs781104228; called by muse, mutect2, varscan2
- TGDS | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54300281; called by muse, varscan2
- TIE1 | c.1514C>T p.T505M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199991616; called by muse, mutect2, varscan2
- TIRAP | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 101/365 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs765930909; called by muse, mutect2, varscan2
- TM4SF5 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs201854269; called by muse, mutect2, varscan2
- TM7SF2 | c.448A>G p.M150V | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs555112713; called by muse, mutect2, varscan2
- TMEM132D | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 67/231 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1313754651, COSV70603289, COSV70606974; called by muse, mutect2, varscan2
- TMEM94 | c.4021C>T p.R1341* | Nonsense Mutation (SNP) | VAF 35/151 reads (23%) | catalogued as rs866341630; called by muse, mutect2, varscan2
- TMX3 | c.1225C>T p.R409* | Nonsense Mutation (SNP) | VAF 78/258 reads (30%) | catalogued as rs772657310, COSV100218339; called by muse, mutect2, varscan2
- TNC | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs369342950; called by muse, mutect2, varscan2
- TP53BP2 | c.428G>A p.R143H (on ENST00000343537 / NM_001031685.3; = p.R14H on NM_005426.2) | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766049032, COSV100636849; called by muse, varscan2
- TRIP11 | c.4442C>T p.A1481V | Missense Mutation (SNP) | VAF 79/306 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs756561387, COSV50971400; called by muse, mutect2, varscan2
- TTF2 | c.2805G>A p.S935= | Splice Region (SNP) | VAF 32/110 reads (29%) | catalogued as rs546932005; called by muse, mutect2, varscan2
- TTN | c.14054A>G p.H4685R (on ENST00000591111; = p.H3758R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/123 reads (33%) | PolyPhen benign (0.053); catalogued as COSV60101818; called by muse, mutect2, varscan2
- TUSC3 | c.368G>A p.C123Y | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV65882329; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | catalogued as rs760251146; called by mutect2, varscan2
- TWIST1 | c.283A>G p.S95G | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs575299986, CM156313, CX013686, COSV54251082; called by muse, mutect2, varscan2
- UACA | c.2393G>A p.R798H | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs530685196; called by muse, mutect2, varscan2
- UBE2Q1 | c.1147C>T p.R383* | Nonsense Mutation (SNP) | VAF 50/152 reads (33%) | catalogued as COSV52725000; called by muse, mutect2, varscan2
- UGDH | c.203dup p.N68Kfs*9 | Frame Shift Ins (INS) | VAF 18/68 reads (26%) | catalogued as rs762979242; called by mutect2, pindel, varscan2
- ULK1 | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as rs569453912; called by muse, mutect2, varscan2
- UNC79 | c.4478del p.K1493Sfs*12 (on ENST00000393151 / NM_001346218.2; = p.K1316Sfs*12 on NM_020818.5) | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | catalogued as rs760213136; called by mutect2, varscan2
- UNCX | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); catalogued as rs1338287240; called by muse, varscan2
- UPF3A | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.19); catalogued as rs1296728016; called by muse, mutect2, varscan2
- USP13 | c.1896dup p.I633Hfs*5 | Frame Shift Ins (INS) | VAF 40/106 reads (38%) | catalogued as rs780272979; called by mutect2, varscan2
- VPS13C | c.4429del p.I1477Lfs*24 (on ENST00000644861 / NM_020821.3; = p.I1434Lfs*24 on NM_017684.5) | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs756149444; called by mutect2, varscan2
- WASHC2C | c.1547del p.K516Rfs*41 | Frame Shift Del (DEL) | VAF 28/141 reads (20%) | catalogued as rs782259587; called by mutect2, pindel, varscan2
- WBP1 | c.608G>A p.C203Y | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV51969492; called by muse, mutect2, varscan2
- WBP4 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as rs749569132; called by muse, mutect2, varscan2
- WNK4 | c.3077C>T p.A1026V | Missense Mutation (SNP) | VAF 133/366 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.162); catalogued as COSV55901826; called by muse, mutect2, varscan2
- WNT10A | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs774127616; called by muse, mutect2, varscan2
- XIRP1 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1041806468; called by muse, mutect2, varscan2
- XPC | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.475); catalogued as COSV53207346; called by muse, mutect2
- ZBTB24 | c.501del p.V168Sfs*19 | Frame Shift Del (DEL) | VAF 132/472 reads (28%) | catalogued as rs780371205; called by mutect2, varscan2
- ZC3HAV1 | c.435del p.F145Lfs*49 | Frame Shift Del (DEL) | VAF 35/113 reads (31%) | catalogued as rs1363033923; called by mutect2, pindel, varscan2
- ZDBF2 | c.5624del p.K1875Rfs*39 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | catalogued as rs770232797, COSV65623567; called by mutect2, varscan2
- ZDHHC12 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV52577525; called by muse, mutect2, varscan2
- ZDHHC3 | c.565A>G p.M189V | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV56102403; called by muse, mutect2, varscan2
- ZDHHC4 | c.344del p.F115Sfs*3 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs34551853; called by mutect2, varscan2
- ZFHX4 | c.6539C>T p.T2180M | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749590793, COSV51454526, COSV99268633; called by muse, mutect2, varscan2
- ZIM3 | c.130C>A p.L44I | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV54143282; called by muse, mutect2, varscan2
- ZNF16 | c.1055G>A p.S352N | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs770375739; called by muse, mutect2, varscan2
- ZNF20 | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs922581532; called by muse, mutect2
- ZNF423 | c.3190A>G p.N1064D (on ENST00000563137 / NM_001379286.1; = p.N1056D on NM_015069.4) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.589); catalogued as COSV99280911; called by muse, mutect2, varscan2
- ZNF469 | c.9367C>T p.R3123C (on ENST00000437464; = p.R3151C on NM_001367624.2) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755567767; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 46/146 reads (32%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF83 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.439); catalogued as rs1318682287; called by muse, mutect2, varscan2
- ZNF880 | c.1611del p.K537Nfs*60 | Frame Shift Del (DEL) | VAF 60/172 reads (35%) | catalogued as rs759348115; called by mutect2, varscan2
- ZNF891 | c.1394G>A p.C465Y | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs1460748584; called by muse, mutect2, varscan2
- ZSCAN20 | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377133729; called by muse, mutect2, varscan2
- AATF | c.1246_1249del p.V416Ifs*34 | Frame Shift Del (DEL) | VAF 19/119 reads (16%) | called by mutect2, pindel, varscan2
- ABCA1 | c.3545C>T p.A1182V | Missense Mutation (SNP) | VAF 84/267 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACBD5 | c.338C>T p.A113V (on ENST00000375888 / NM_001352568.1; = p.A115V on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/256 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, varscan2
- ADAMTS5 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAR | c.2189G>A p.G730D | Missense Mutation (SNP) | VAF 107/295 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADARB2 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ADGRG4 | c.378G>T p.W126C | Missense Mutation (SNP) | VAF 96/322 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- AFM | c.919A>G p.I307V | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- AKAP13 | c.1829G>A p.G610D | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.10262C>T p.A3421V | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ANKRD11 | c.7159C>T p.R2387C | Missense Mutation (SNP) | VAF 79/321 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD12 | c.1927del p.M643Wfs*8 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- ANKS1B | c.150dup p.N51Qfs*22 | Frame Shift Ins (INS) | VAF 42/161 reads (26%) | called by mutect2, pindel, varscan2
- ANLN | c.2695del p.T899Hfs*16 | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | called by mutect2, varscan2
- AP2A1 | c.992G>A p.C331Y | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- AR | c.2068C>T p.H690Y | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARAP2 | c.4094del p.N1365Ifs*21 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | called by mutect2, pindel, varscan2
- ARHGEF10 | c.2194del p.A732Pfs*29 (on ENST00000398564; = p.A707Pfs*29 on NM_014629.4) | Frame Shift Del (DEL) | VAF 86/339 reads (25%) | called by mutect2, pindel, varscan2
- ARHGEF18 | c.2611C>T p.R871C (on ENST00000359920 / NM_001130955.2; = p.R767C on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARID1A | c.4_16dup p.A6? | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | called by mutect2, varscan2
- ARIH2 | c.974T>C p.M325T | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ATAD2 | c.2474dup p.L825Ffs*10 | Frame Shift Ins (INS) | VAF 32/121 reads (26%) | called by mutect2, pindel, varscan2
- ATP10D | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ATP1A3 | c.2095del p.Q699Sfs*19 (on ENST00000545399 / NM_001256214.2; = p.Q686Sfs*19 on NM_152296.5) | Frame Shift Del (DEL) | VAF 103/458 reads (22%) | called by mutect2, pindel, varscan2
- ATP8A1 | c.2896+2T>C p.X966_splice | Splice Site (SNP) | VAF 34/125 reads (27%) | called by muse, mutect2, varscan2
- ATXN2L | c.3053C>A p.P1018H | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ATXN7 | c.1345A>G p.T449A | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.065); called by muse, mutect2
- AXL | c.2447C>T p.P816L (on ENST00000301178 / NM_021913.5; = p.P807L on NM_001699.6) | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAG6 | c.344del p.P115Lfs*53 | Frame Shift Del (DEL) | VAF 43/164 reads (26%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.6895G>T p.G2299W | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BANK1 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- BEX3 | c.330G>A p.M110I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BEX4 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- BRCA1 | c.4483dup p.R1495Kfs*6 | Frame Shift Ins (INS) | VAF 60/228 reads (26%) | called by mutect2, pindel, varscan2
- BRSK1 | c.2210C>T p.A737V | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BSN | c.10169del p.P3390Hfs*97 | Frame Shift Del (DEL) | VAF 58/192 reads (30%) | called by mutect2, varscan2
- BTNL9 | c.1121T>C p.L374P | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C17orf80 | c.1562del p.P521Lfs*11 | Frame Shift Del (DEL) | VAF 28/81 reads (35%) | called by mutect2, pindel, varscan2
- C19orf54 | c.323+1G>A p.X108_splice | Splice Site (SNP) | VAF 54/206 reads (26%) | called by muse, mutect2, varscan2
- CAMTA1 | c.3093del p.S1032Afs*14 | Frame Shift Del (DEL) | VAF 30/124 reads (24%) | called by mutect2, pindel
- CASK | c.1667T>C p.L556P | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CBFA2T3 | c.831del p.I278Sfs*44 | Frame Shift Del (DEL) | VAF 44/173 reads (25%) | called by mutect2, pindel, varscan2
- CCDC77 | c.123del p.L42Cfs*36 | Frame Shift Del (DEL) | VAF 64/210 reads (30%) | called by mutect2, pindel, varscan2
- CCL25 | c.80T>C p.F27S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- CD93 | c.1307dup p.L438Pfs*46 | Frame Shift Ins (INS) | VAF 29/110 reads (26%) | called by mutect2, pindel, varscan2
- CDH10 | c.1920del p.E641Sfs*3 | Frame Shift Del (DEL) | VAF 36/140 reads (26%) | called by mutect2, pindel, varscan2
- CDH17 | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- CDHR1 | c.2099A>C p.K700T | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2
- CEP350 | c.709A>G p.K237E | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2
- CGN | c.1559A>G p.Q520R | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- CHD9 | c.2280del p.F760Lfs*16 | Frame Shift Del (DEL) | VAF 22/81 reads (27%) | called by mutect2, pindel, varscan2
- CHMP4B | c.67del p.Q23Rfs*14 | Frame Shift Del (DEL) | VAF 32/119 reads (27%) | called by mutect2, pindel, varscan2
- CHMP5 | c.315+1G>A p.X105_splice | Splice Site (SNP) | VAF 46/126 reads (37%) | called by muse, mutect2, varscan2
- CLCN7 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLPTM1L | c.668A>C p.K223T | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- CNGA2 | c.1594del p.M532Wfs*29 | Frame Shift Del (DEL) | VAF 25/103 reads (24%) | called by mutect2, pindel, varscan2
- CNOT10 | c.1816A>T p.I606F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2
- CNST | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 53/175 reads (30%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.2873G>A p.G958E | Missense Mutation (SNP) | VAF 92/411 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL27A1 | c.5399del p.G1800Vfs*64 | Frame Shift Del (DEL) | VAF 66/240 reads (28%) | called by mutect2, pindel, varscan2
- COL9A3 | c.647del p.P216Lfs*317 | Frame Shift Del (DEL) | VAF 55/195 reads (28%) | called by mutect2, pindel, varscan2
- CTSF | c.732C>A p.F244L | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CTTN | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- CYP2C9 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CYP4F3 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CYP8B1 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- DENND4B | c.3059del p.G1020Afs*6 | Frame Shift Del (DEL) | VAF 24/226 reads (11%) | called by pindel, varscan2
- DENND5A | c.1765dup p.I589Nfs*5 | Frame Shift Ins (INS) | VAF 94/327 reads (29%) | called by mutect2, pindel, varscan2
- DHX30 | c.1801C>T p.R601* (on ENST00000445061 / NM_138615.3; = p.R562* on NM_014966.3) | Nonsense Mutation (SNP) | VAF 57/200 reads (29%) | called by muse, mutect2, varscan2
- DLEU7 | c.94dup p.D32Gfs*64 | Frame Shift Ins (INS) | VAF 38/124 reads (31%) | called by mutect2, pindel
- DNHD1 | c.8371T>C p.W2791R | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- DOP1A | c.6764A>G p.E2255G | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EIF3G | c.948-3del | Splice Region (DEL) | VAF 50/181 reads (28%) | called by mutect2, pindel
- EIF4G3 | c.1689del p.V564* | Frame Shift Del (DEL) | VAF 61/254 reads (24%) | called by mutect2, pindel, varscan2
- ELP3 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.285); called by muse, varscan2
- EMILIN1 | c.1302dup p.L435Afs*74 | Frame Shift Ins (INS) | VAF 17/89 reads (19%) | called by mutect2, pindel, varscan2
- EP300 | c.1837C>T p.R613W | Missense Mutation (SNP) | VAF 115/386 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ESYT2 | c.290-8C>T | Splice Region (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2
- EVC2 | c.283G>T p.V95L | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EVI5 | c.416dup p.R140Kfs*4 | Frame Shift Ins (INS) | VAF 28/102 reads (27%) | called by pindel, varscan2
- EXOC6B | c.1053dup p.V352Cfs*3 | Frame Shift Ins (INS) | VAF 31/116 reads (27%) | called by mutect2, pindel, varscan2
- EXT1 | c.1655C>A p.P552H | Missense Mutation (SNP) | VAF 75/269 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM102A | c.697G>A p.A233T (on ENST00000373095 / NM_001035254.3; = p.A91T on NM_203305.2) | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM184B | c.2464C>T p.R822C | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- FAM189A1 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- FAM189A2 | c.796C>A p.L266I | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FAM193B | c.2225A>C p.Q742P | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- FBXL17 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FGF3 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FGL2 | c.746del p.G249Efs*44 | Frame Shift Del (DEL) | VAF 61/225 reads (27%) | called by mutect2, pindel, varscan2
- FIGN | c.799del p.A267Hfs*34 | Frame Shift Del (DEL) | VAF 42/160 reads (26%) | called by mutect2, varscan2
- FLNA | c.5188C>T p.H1730Y (on ENST00000369850 / NM_001110556.2; = p.H1722Y on NM_001456.3) | Missense Mutation (SNP) | VAF 96/329 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- FMN1 | c.3577G>T p.G1193* (on ENST00000616417 / NM_001277313.2; = p.G970* on NM_001103184.4) | Nonsense Mutation (SNP) | VAF 53/197 reads (27%) | called by muse, mutect2, varscan2
- FMNL3 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 80/263 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- FOXK1 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 93/325 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FOXM1 | c.2008del p.E671Nfs*12 | Frame Shift Del (DEL) | VAF 46/157 reads (29%) | called by mutect2, pindel, varscan2
- FRAS1 | c.5185G>A p.A1729T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, varscan2
- FRMPD2 | c.3673C>T p.P1225S | Missense Mutation (SNP) | VAF 60/298 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- FUBP3 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FZD7 | c.1307G>A p.G436D | Missense Mutation (SNP) | VAF 102/367 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GEMIN7 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GGT1 | c.932T>C p.L311P | Missense Mutation (SNP) | VAF 151/464 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- GLP2R | c.248G>A p.C83Y | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLYCTK | c.-40+7C>G | Splice Region (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- GMNC | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR82 | c.122del p.L41* | Frame Shift Del (DEL) | VAF 27/99 reads (27%) | called by mutect2, pindel, varscan2
- GPRIN1 | c.2365C>T p.R789W | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- GPS1 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- GSDME | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 106/371 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- GSK3A | c.1307_1308del p.L436Qfs*27 | Frame Shift Del (DEL) | VAF 54/189 reads (29%) | called by pindel, varscan2
- GTF3C1 | c.4992del p.N1665Tfs*11 | Frame Shift Del (DEL) | VAF 36/129 reads (28%) | called by mutect2, pindel, varscan2
- GTF3C4 | c.1051A>G p.K351E | Missense Mutation (SNP) | VAF 58/229 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GUCA2B | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H1-8 | c.361del p.A121Pfs*7 | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | called by mutect2, pindel, varscan2
- HAUS2 | c.119C>A p.T40K | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- HDAC8 | c.15G>T p.E5D | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HDGF | c.149dup p.G51Rfs*63 | Frame Shift Ins (INS) | VAF 32/114 reads (28%) | called by mutect2, varscan2
- HECTD1 | c.4594G>A p.A1532T | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- HECTD2 | c.1661A>G p.D554G | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HENMT1 | c.1084A>G p.M362V | Missense Mutation (SNP) | VAF 80/260 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, varscan2
- HERC2 | c.1990T>C p.C664R | Missense Mutation (SNP) | VAF 96/315 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HNRNPH1 | c.634dup p.R212Kfs*6 | Frame Shift Ins (INS) | VAF 41/131 reads (31%) | called by mutect2, pindel, varscan2
- HPSE2 | c.1272del p.F424Lfs*28 | Frame Shift Del (DEL) | VAF 69/287 reads (24%) | called by mutect2, pindel, varscan2
- HSH2D | c.704A>G p.D235G | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- HSPA9 | c.1025T>C p.L342S | Missense Mutation (SNP) | VAF 140/444 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HSPB8 | c.306dup p.S103Ffs*2 | Frame Shift Ins (INS) | VAF 35/151 reads (23%) | called by mutect2, pindel, varscan2
- HTR7 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IGSF1 | c.2452G>A p.A818T | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ILF3 | c.1201del p.Q401Rfs*3 | Frame Shift Del (DEL) | VAF 61/179 reads (34%) | called by mutect2, pindel, varscan2
- INPPL1 | c.561del p.G188Afs*10 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- INTS5 | c.1421del p.L474* | Frame Shift Del (DEL) | VAF 65/248 reads (26%) | called by mutect2, pindel, varscan2
- IP6K3 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 32/133 reads (24%) | called by muse, mutect2, varscan2
- IRX1 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IRX3 | c.847G>T p.G283* | Nonsense Mutation (SNP) | VAF 40/151 reads (26%) | called by muse, mutect2, varscan2
- ISL1 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ITGAE | c.2523G>A p.Q841= | Splice Region (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- ITGB4 | c.263_264del p.E88Gfs*5 | Frame Shift Del (DEL) | VAF 92/338 reads (27%) | called by pindel, varscan2
- ITIH5 | c.1987C>G p.L663V | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ITM2A | c.242dup p.S82Efs*12 | Frame Shift Ins (INS) | VAF 28/90 reads (31%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 96/178 reads (54%) | called by mutect2, varscan2
- JPH2 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- JPH3 | c.1816dup p.E606Gfs*112 | Frame Shift Ins (INS) | VAF 74/256 reads (29%) | called by mutect2, pindel, varscan2
- KANSL1 | c.1463del p.P488Qfs*15 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | called by mutect2, pindel, varscan2
- KAT6A | c.4469C>T p.P1490L | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNC3 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 120/372 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- KIAA1217 | c.213del p.R73Efs*22 | Frame Shift Del (DEL) | VAF 32/146 reads (22%) | called by mutect2, varscan2
- KIAA1217 | c.2005C>T p.Q669* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- KLHDC4 | c.1308G>A p.M436I | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- KNCN | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 34/144 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- KRTAP26-1 | c.395A>G p.Y132C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- L3HYPDH | c.826G>T p.G276* | Nonsense Mutation (SNP) | VAF 34/119 reads (29%) | called by muse, mutect2, varscan2
- LCOR | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- LHX1 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 88/265 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LINGO1 | c.1384C>T p.R462* | Nonsense Mutation (SNP) | VAF 67/225 reads (30%) | called by muse, mutect2, varscan2
- LPIN2 | c.2328-6del | Splice Region (DEL) | VAF 68/246 reads (28%) | called by mutect2, pindel, varscan2
- LRRC25 | c.661T>C p.Y221H | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC71 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- LRRN2 | c.474del p.R159Gfs*19 | Frame Shift Del (DEL) | VAF 106/363 reads (29%) | called by mutect2, pindel, varscan2
- LTBP3 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 61/267 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LTF | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- LVRN | c.1856del p.N619Mfs*7 | Frame Shift Del (DEL) | VAF 29/105 reads (28%) | called by mutect2, pindel, varscan2
- LYPLA1 | c.101+6T>A | Splice Region (SNP) | VAF 36/132 reads (27%) | called by muse, mutect2, varscan2
- LYST | c.10441C>T p.P3481S | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MACROH2A2 | c.438del p.K147Rfs*53 | Frame Shift Del (DEL) | VAF 41/152 reads (27%) | called by mutect2, pindel, varscan2
- MAD2L2 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.322); called by muse, mutect2
- MAP3K11 | c.77dup p.G27Rfs*7 | Frame Shift Ins (INS) | VAF 12/71 reads (17%) | called by pindel, varscan2
- MAP4K4 | c.2596_2597del p.Q866Dfs*5 (on ENST00000347699 / NM_001242559.2; = p.Q784Dfs*5 on NM_004834.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 30/126 reads (24%) | called by mutect2, pindel, varscan2
- MAST3 | c.2850del p.I951Sfs*74 | Frame Shift Del (DEL) | VAF 101/352 reads (29%) | called by mutect2, pindel, varscan2
- MBOAT7 | c.1054A>G p.S352G | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEPE | c.281A>G p.Q94R | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- MICAL3 | c.2037del p.K680Rfs*25 | Frame Shift Del (DEL) | VAF 23/124 reads (19%) | called by mutect2, pindel, varscan2
- MLN | c.299C>T p.T100I | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MPRIP | c.1058del p.P353Qfs*30 | Frame Shift Del (DEL) | VAF 21/65 reads (32%) | called by mutect2, pindel, varscan2
- MUC19 | c.484-2A>G p.X162_splice | Splice Site (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- MYBL1 | c.254T>C p.L85S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- MYL1 | c.295A>G p.S99G | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MYLK2 | c.734G>A p.C245Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- MYO9A | c.7119dup p.G2374Wfs*4 | Frame Shift Ins (INS) | VAF 17/206 reads (8%) | called by mutect2, pindel
- NCBP1 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- NDUFB10 | c.281A>G p.Q94R | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NETO2 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NFASC | c.494del p.P165Rfs*12 (on ENST00000339876 / NM_001378329.1; = p.P159Rfs*12 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 76/268 reads (28%) | called by mutect2, pindel, varscan2
- NKTR | c.3448A>G p.N1150D | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- NMS | c.407T>C p.L136P | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, varscan2
- NOL7 | c.622+2T>C p.X208_splice | Splice Site (SNP) | VAF 22/103 reads (21%) | called by muse, varscan2
- NOS1 | c.2508del p.N837Tfs*46 | Frame Shift Del (DEL) | VAF 73/270 reads (27%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.7455del p.S2486Rfs*103 | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | called by mutect2, pindel, varscan2
- NPLOC4 | c.1669+6T>C | Splice Region (SNP) | VAF 81/253 reads (32%) | called by muse, mutect2, varscan2
- NR1H4 | c.340G>A p.A114T (on ENST00000551379 / NM_001206993.2; = p.A104T on NM_005123.4) | Missense Mutation (SNP) | VAF 89/297 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NSD1 | c.6053T>C p.F2018S | Missense Mutation (SNP) | VAF 93/378 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NYAP1 | c.2021C>A p.P674H | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- ODF2L | c.768del p.F256Lfs*37 | Frame Shift Del (DEL) | VAF 35/113 reads (31%) | called by mutect2, pindel, varscan2
- OLIG2 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR51E2 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 84/290 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- OR5P2 | c.870C>A p.N290K | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OSBPL6 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- OVCA2 | c.640del p.Q214Sfs*46 | Frame Shift Del (DEL) | VAF 40/165 reads (24%) | called by mutect2, pindel, varscan2
- PATJ | c.2385A>T p.E795D | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHAC1 | c.1560del p.H522Ifs*4 | Frame Shift Del (DEL) | VAF 44/148 reads (30%) | called by mutect2, pindel, varscan2
- PCDHGB4 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PHC1 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 29/76 reads (38%) | called by muse, mutect2
- PIK3AP1 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3R1 | c.1333_1356del p.V445_Y452del (on ENST00000521381 / NM_181523.3; = p.V175_Y182del on NM_181504.4) | In Frame Del (DEL) | VAF 11/65 reads (17%) | called by mutect2, pindel
- PKD1 | c.8621T>C p.V2874A | Missense Mutation (SNP) | VAF 174/582 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- PKD2L1 | c.2312del p.G771Efs*19 | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- PKDCC | c.1132del p.V378Wfs*112 | Frame Shift Del (DEL) | VAF 38/141 reads (27%) | called by mutect2, pindel, varscan2
- PKN2 | c.1364del p.L455* | Frame Shift Del (DEL) | VAF 52/189 reads (28%) | called by mutect2, pindel, varscan2
- PKN2 | c.2735del p.K912Sfs*7 | Frame Shift Del (DEL) | VAF 58/208 reads (28%) | called by mutect2, pindel, varscan2
- PLCB3 | c.2752del p.R918Afs*95 | Frame Shift Del (DEL) | VAF 32/146 reads (22%) | called by mutect2, pindel, varscan2
- PLEKHG7 | c.530+6T>C | Splice Region (SNP) | VAF 35/132 reads (27%) | called by muse, mutect2, varscan2
- PLK3 | c.694C>A p.L232M | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- POU6F1 | c.1120del p.L374Cfs*81 | Frame Shift Del (DEL) | VAF 32/113 reads (28%) | called by mutect2, pindel, varscan2
- PPP2R5B | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 71/244 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- PRDM2 | c.4277del p.N1426Ifs*3 | Frame Shift Del (DEL) | VAF 42/160 reads (26%) | called by mutect2, varscan2
- PRDM9 | c.1064T>A p.V355D | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- PRELP | c.242del p.P81Lfs*61 | Frame Shift Del (DEL) | VAF 35/126 reads (28%) | called by mutect2, pindel, varscan2
- PROS1 | c.862T>C p.C288R | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRPF6 | c.2801C>T p.A934V | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.692-11_710delinsTGCCGCAGAGCTGCAGAGAGACAA p.X231_splice (on ENST00000352766; = p.X108_splice on NM_181334.5) | Splice Site (DEL) | VAF 26/71 reads (37%) | called by pindel, varscan2*
- PTAR1 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 73/251 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, varscan2
- PTPRN2 | c.1643+1G>C p.X548_splice | Splice Site (SNP) | VAF 44/151 reads (29%) | called by muse, mutect2, varscan2
- PYGL | c.215A>G p.Q72R | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- PZP | c.2685G>T p.E895D | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAB10 | c.359T>G p.L120R | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RAI1 | c.4438_4439del p.R1480Gfs*9 | Frame Shift Del (DEL) | VAF 41/173 reads (24%) | called by mutect2, pindel, varscan2
- RAPGEF6 | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RBM25 | c.1040G>T p.R347L | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- RBM28 | c.863G>A p.S288N | Missense Mutation (SNP) | VAF 66/237 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- RELN | c.9687G>T p.E3229D | Missense Mutation (SNP) | VAF 114/404 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- RETN | c.193del p.R65Efs*70 | Frame Shift Del (DEL) | VAF 82/267 reads (31%) | called by mutect2, pindel, varscan2
- RIC1 | c.2657C>T p.T886I | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RIOX1 | c.1114A>G p.T372A | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- RPAP1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- RPS3 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, varscan2
- RSL24D1 | c.269-5del | Splice Region (DEL) | VAF 24/107 reads (22%) | called by mutect2, pindel, varscan2
- RYR3 | c.6195G>A p.M2065I | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.141); called by muse, mutect2
- SAAL1 | c.151A>G p.N51D | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SALL3 | c.464del p.P155Qfs*12 | Frame Shift Del (DEL) | VAF 24/91 reads (26%) | called by mutect2, pindel, varscan2
- SAMD3 | c.1260del p.F420Lfs*4 | Frame Shift Del (DEL) | VAF 34/139 reads (24%) | called by mutect2, pindel, varscan2
- SATB1 | c.1150A>G p.K384E | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SBNO2 | c.2245G>C p.E749Q | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SESN3 | c.503T>C p.L168P | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEZ6 | c.915del p.P306Lfs*27 | Frame Shift Del (DEL) | VAF 30/160 reads (19%) | called by mutect2, pindel, varscan2
- SF3B3 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 82/319 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- SGK1 | c.8A>G p.N3S | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SH3BP5 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- SHC1 | c.1355G>A p.G452D (on ENST00000368445 / NM_183001.5; = p.G343D on NM_003029.5) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SHISA6 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- SIK3 | c.142G>A p.A48T (on ENST00000445177 / NM_001366686.2; = p.A54T on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated, low confidence (0.31); called by muse, mutect2
- SLC17A7 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 10/249 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); called by muse, mutect2
- SLC20A1 | c.661C>T p.L221= | Splice Region (SNP) | VAF 103/367 reads (28%) | called by muse, mutect2, varscan2
- SLC24A4 | c.1550T>C p.M517T | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC25A32 | c.248A>G p.Q83R | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (0.84); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC25A41 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | called by muse, varscan2
- SLC25A43 | c.97dup p.L33Pfs*68 | Frame Shift Ins (INS) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- SLC9A6 | c.488C>G p.A163G | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); called by muse, varscan2
- SMC2 | c.820del p.I274* | Frame Shift Del (DEL) | VAF 33/111 reads (30%) | called by mutect2, pindel, varscan2
- SNRK | c.360dup p.A121Cfs*12 | Frame Shift Ins (INS) | VAF 22/95 reads (23%) | called by mutect2, pindel, varscan2
- SORBS1 | c.1096del p.V366Wfs*2 (on ENST00000361941 / NM_001034954.2; = p.V202Wfs*2 on NM_006434.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 57/225 reads (25%) | called by pindel, varscan2
- SPATC1L | c.877G>A p.A293T (on ENST00000291672 / NM_001142854.2; = p.A139T on NM_032261.5) | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SPINK7 | c.17del p.G6Vfs*66 | Frame Shift Del (DEL) | VAF 51/169 reads (30%) | called by mutect2, pindel, varscan2
- SPTLC1 | c.335T>C p.L112S | Missense Mutation (SNP) | VAF 65/266 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- STARD9 | c.10451dup p.Q3485Afs*53 | Frame Shift Ins (INS) | VAF 49/193 reads (25%) | called by mutect2, pindel, varscan2
- STXBP5 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SUV39H1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SUZ12 | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 78/261 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE1 | c.13924A>C p.S4642R (on ENST00000367255 / NM_182961.4; = p.S4571R on NM_033071.3) | Missense Mutation (SNP) | VAF 163/559 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TAS2R1 | c.576dup p.A193Cfs*91 | Frame Shift Ins (INS) | VAF 41/143 reads (29%) | called by mutect2, pindel, varscan2
- TAX1BP3 | c.40-1G>A p.X14_splice | Splice Site (SNP) | VAF 18/74 reads (24%) | called by muse, varscan2
- TCEA3 | c.851G>T p.R284M | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TCF20 | c.189_191del p.A68del | In Frame Del (DEL) | VAF 76/234 reads (32%) | called by pindel, varscan2
- TDRD5 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TFAP2B | c.219del p.Y74Tfs*22 | Frame Shift Del (DEL) | VAF 56/201 reads (28%) | called by mutect2, varscan2
- TGFBR3 | c.1936A>G p.N646D | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- TGFBR3L | c.723dup p.R242Qfs*14 | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- TLN2 | c.1427A>G p.Q476R | Missense Mutation (SNP) | VAF 71/254 reads (28%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- TMEM161B | c.692dup p.L232Pfs*101 | Frame Shift Ins (INS) | VAF 74/262 reads (28%) | called by pindel, varscan2
- TMEM181 | c.1199del p.L400* | Frame Shift Del (DEL) | VAF 45/140 reads (32%) | called by mutect2, pindel, varscan2
- TMEM262 | c.101T>C p.I34T (on ENST00000530719 / NM_001282448.1; = p.I32T on NM_001242631.2) | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- TMPRSS9 | c.2864T>C p.L955P (on ENST00000648592; = p.L921P on NM_182973.2) | Missense Mutation (SNP) | VAF 96/315 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- TMUB2 | c.497G>A p.C166Y (on ENST00000538716 / NM_001353177.2; = p.C146Y on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TP53BP2 | c.594del p.V199* (on ENST00000343537 / NM_001031685.3; = p.V70* on NM_005426.2) | Frame Shift Del (DEL) | VAF 38/147 reads (26%) | called by mutect2, varscan2
- TPM3 | c.377+1G>C p.X126_splice | Splice Site (SNP) | VAF 105/375 reads (28%) | called by muse, mutect2, varscan2
- TRIML1 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- TRPM2 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- TTC21B | c.560G>A p.C187Y | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, varscan2
- U2SURP | c.1230+13dup | Splice Region (INS) | VAF 17/65 reads (26%) | called by mutect2, pindel
- U2SURP | c.1616G>T p.R539M | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ULBP1 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 70/300 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ULBP2 | c.574G>T p.G192* | Nonsense Mutation (SNP) | VAF 88/279 reads (32%) | called by muse, mutect2, varscan2
- UMPS | c.961A>G p.T321A | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- UNC79 | c.1157C>T p.T386I (on ENST00000393151 / NM_001346218.2; = p.T209I on NM_020818.5) | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- URGCP | c.1070C>T p.A357V (on ENST00000453200 / NM_001077663.3; = p.A348V on NM_017920.4) | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- VPS9D1 | c.1676del p.P559Rfs*22 | Frame Shift Del (DEL) | VAF 32/130 reads (25%) | called by mutect2, pindel
- WDR17 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- WDR81 | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XCL1 | c.17T>C p.L6P | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XDH | c.3766G>A p.A1256T | Missense Mutation (SNP) | VAF 85/305 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- XPO1 | c.1694T>C p.V565A | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- YARS1 | c.907-1G>T p.X303_splice | Splice Site (SNP) | VAF 52/205 reads (25%) | called by muse, mutect2, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | called by mutect2, pindel, varscan2
- ZC3H12B | c.1475G>A p.S492N | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZC3H12C | c.2336G>T p.R779M | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.894); called by muse, mutect2
- ZCCHC18 | c.246del p.K82Nfs*5 | Frame Shift Del (DEL) | VAF 20/226 reads (9%) | called by mutect2, pindel
- ZEB2 | c.2248A>C p.S750R | Missense Mutation (SNP) | VAF 73/262 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX3 | c.2287del p.E763Sfs*61 | Frame Shift Del (DEL) | VAF 79/282 reads (28%) | called by mutect2, pindel, varscan2
- ZNF212 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF335 | c.3323G>A p.C1108Y | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF43 | c.1843del p.I615Ffs*28 | Frame Shift Del (DEL) | VAF 39/130 reads (30%) | called by mutect2, varscan2
- ZNF460 | c.665A>G p.K222R | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF506 | c.345del p.G116Afs*5 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- ZNF544 | c.488del p.G163Efs*9 | Frame Shift Del (DEL) | VAF 42/105 reads (40%) | called by mutect2, pindel, varscan2
- ZNF624 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZNF800 | c.1688del p.K563Sfs*7 | Frame Shift Del (DEL) | VAF 51/165 reads (31%) | called by mutect2, pindel, varscan2
- ZNF853 | c.1432C>T p.R478W | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ZP4 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ADAMTS19 | c.183G>A p.G61= | Silent (SNP) | VAF 16/46 reads (35%) | called by muse, varscan2
- ADRA2B | c.504G>A p.Q168= | Silent (SNP) | VAF 107/361 reads (30%) | called by muse, mutect2, varscan2
- AEN | c.721C>T p.L241= | Silent (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- AFF2 | c.2376G>A p.L792= | Silent (SNP) | VAF 65/190 reads (34%) | called by muse, mutect2, varscan2
- AGAP1 | c.1362C>T p.S454= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as rs1216753025; called by muse, mutect2, varscan2
- ALMS1 | c.75A>G p.E25= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs13009043; called by muse, varscan2
- ANGPTL6 | c.588G>A p.L196= | Silent (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2
- ANGPTL8 | c.480C>T p.S160= | Silent (SNP) | VAF 33/109 reads (30%) | called by muse, mutect2, varscan2
- ANKK1 | c.930C>T p.C310= | Silent (SNP) | VAF 39/146 reads (27%) | catalogued as COSV58271352; called by muse, mutect2, varscan2
- APOC4-APOC2 | c.51C>T p.C17= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as rs764411553; called by muse, mutect2, varscan2
- APOH | c.585T>C p.T195= | Silent (SNP) | VAF 18/68 reads (26%) | called by mutect2, varscan2
- ARHGAP33 | c.756G>A p.P252= | Silent (SNP) | VAF 50/163 reads (31%) | catalogued as rs750073892; called by muse, mutect2, varscan2
- ARHGEF15 | c.1185G>A p.L395= | Silent (SNP) | VAF 38/170 reads (22%) | called by muse, mutect2, varscan2
- ARHGEF17 | c.780G>A p.Q260= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs1312973468; called by muse, mutect2, varscan2
- ARRDC2 | c.9C>T p.F3= | Silent (SNP) | VAF 104/304 reads (34%) | called by muse, mutect2, varscan2
- ASIC1 | c.186G>A p.T62= | Silent (SNP) | VAF 68/229 reads (30%) | catalogued as rs61735039, COSV57316837; called by muse, mutect2, varscan2
- ASMTL | c.342G>A p.L114= | Silent (SNP) | VAF 62/239 reads (26%) | called by muse, mutect2, varscan2
- ATP8A2 | c.1200T>C p.Y400= | Silent (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- B3GNT4 | c.363C>T p.L121= | Silent (SNP) | VAF 46/155 reads (30%) | catalogued as rs753512839, COSV99928141; called by muse, mutect2, varscan2
- BBOX1 | c.162A>G p.L54= | Silent (SNP) | VAF 37/150 reads (25%) | catalogued as rs1215615371; called by muse, varscan2
- BCL3 | c.969G>A p.P323= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV51234324; called by muse, mutect2, varscan2
- BSND | c.909C>T p.A303= | Silent (SNP) | VAF 72/210 reads (34%) | catalogued as rs756452755, COSV64870785; ClinVar: likely benign; called by muse, mutect2
- CA9 | c.468C>T p.C156= | Silent (SNP) | VAF 37/113 reads (33%) | called by muse, mutect2, varscan2
- CABP7 | c.507C>T p.P169= | Silent (SNP) | VAF 36/125 reads (29%) | catalogued as rs569823731, COSV53362551, COSV53362709; called by muse, mutect2, varscan2
- CACNA1B | c.2341C>A p.R781= | Silent (SNP) | VAF 56/205 reads (27%) | catalogued as COSV53134084; called by muse, mutect2, varscan2
- CACNA1I | c.6423G>A p.P2141= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- CAPN3 | c.261C>T p.L87= | Silent (SNP) | VAF 67/211 reads (32%) | called by muse, mutect2, varscan2
- CARNMT1 | c.828T>C p.P276= | Silent (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- CDC73 | c.1293C>T p.P431= | Silent (SNP) | VAF 68/245 reads (28%) | called by muse, mutect2, varscan2
- CDH16 | c.1335C>T p.H445= | Silent (SNP) | VAF 55/200 reads (28%) | catalogued as rs370505812, COSV55335447; called by muse, mutect2, varscan2
- CDYL2 | c.1305C>T p.T435= | Silent (SNP) | VAF 68/207 reads (33%) | catalogued as rs181063533, COSV73654273; called by muse, mutect2, varscan2
- CEP63 | c.1338T>C p.G446= | Silent (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- CHRNA1 | c.51C>T p.L17= | Silent (SNP) | VAF 135/447 reads (30%) | catalogued as rs751402231; ClinVar: likely benign; called by muse, mutect2, varscan2
- CILP2 | c.2397C>T p.A799= | Silent (SNP) | VAF 31/97 reads (32%) | called by muse, mutect2, varscan2
- CLCN4 | c.1524A>C p.A508= | Silent (SNP) | VAF 42/137 reads (31%) | called by muse, mutect2, varscan2
- CLUAP1 | c.1146C>T p.D382= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as COSV57089281; called by muse, mutect2, varscan2
- CNTNAP1 | c.3090G>A p.R1030= | Silent (SNP) | VAF 71/244 reads (29%) | catalogued as rs1452617069; called by muse, mutect2, varscan2
- COA4 | c.165G>A p.Q55= | Silent (SNP) | VAF 60/207 reads (29%) | called by muse, mutect2, varscan2
- COL27A1 | c.4494C>T p.P1498= | Silent (SNP) | VAF 45/165 reads (27%) | catalogued as rs145117909; called by muse, mutect2, varscan2
- CSK | c.930C>T p.F310= | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as rs763228212, COSV54972744; called by muse, mutect2, varscan2
- CTBP1 | c.177G>A p.T59= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs772691300, COSV99337425, COSV99337663; called by muse, mutect2, varscan2
- CYB561A3 | c.34C>T p.L12= | Silent (SNP) | VAF 42/119 reads (35%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.879C>T p.S293= | Silent (SNP) | VAF 44/154 reads (29%) | catalogued as rs754672145, COSV64421863, COSV64422822; called by muse, mutect2, varscan2
- DDX24 | c.903T>C p.D301= | Silent (SNP) | VAF 44/151 reads (29%) | called by muse, mutect2, varscan2
- DLGAP3 | c.2280C>T p.P760= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as rs746992705, COSV99333117; called by muse, mutect2, varscan2
- DNAAF2 | c.327C>T p.G109= | Silent (SNP) | VAF 131/424 reads (31%) | called by muse, mutect2, varscan2
- DNAI1 | c.1152C>T p.S384= | Silent (SNP) | VAF 98/347 reads (28%) | catalogued as rs145549023; called by muse, mutect2, varscan2
- DRD5 | c.102G>A p.P34= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1252108593, COSV58577357; called by muse, mutect2, varscan2
- DSCAML1 | c.5706C>T p.D1902= (on ENST00000321322; = p.D1842= on NM_020693.4) | Silent (SNP) | VAF 88/279 reads (32%) | catalogued as rs1363703301; called by muse, mutect2, varscan2
- DYNC1H1 | c.12189C>T p.N4063= | Silent (SNP) | VAF 126/436 reads (29%) | catalogued as rs1247191267; called by muse, mutect2, varscan2
- DYNC2I1 | c.2211G>A p.T737= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as rs370735031; called by muse, mutect2
- ENOX2 | c.180A>G p.L60= (on ENST00000338144 / NM_001382520.1; = p.L31= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV57653221; called by muse, mutect2, varscan2
- EPB41L1 | c.2388C>T p.Y796= | Silent (SNP) | VAF 110/398 reads (28%) | catalogued as rs746792333; called by muse, mutect2, varscan2
- ERF | c.1026C>A p.P342= | Silent (SNP) | VAF 43/165 reads (26%) | called by muse, mutect2, varscan2
- ETV3L | c.21T>C p.A7= | Silent (SNP) | VAF 48/163 reads (29%) | called by muse, mutect2, varscan2
- EXOSC6 | c.744C>T p.C248= | Silent (SNP) | VAF 57/147 reads (39%) | catalogued as rs777228220; called by muse, mutect2, varscan2
- FAM160B2 | c.867C>T p.C289= | Silent (SNP) | VAF 45/156 reads (29%) | catalogued as rs758214577; called by muse, mutect2, varscan2
- FAM83H | c.342C>A p.T114= | Silent (SNP) | VAF 24/106 reads (23%) | called by muse, mutect2
- FANCD2 | c.2238C>T p.N746= | Silent (SNP) | VAF 31/304 reads (10%) | catalogued as rs35817402, COSV55032797; called by muse, mutect2
- FLNB | c.933G>A p.K311= | Silent (SNP) | VAF 98/344 reads (28%) | catalogued as rs200745639; called by muse, mutect2, varscan2
- FN1 | c.411C>T p.I137= | Silent (SNP) | VAF 73/288 reads (25%) | catalogued as rs201434534, COSV60546683; called by muse, mutect2, varscan2
- FOXD3 | c.501C>T p.I167= | Silent (SNP) | VAF 122/424 reads (29%) | called by muse, mutect2, varscan2
- GOLGA4 | c.6543G>A p.V2181= | Silent (SNP) | VAF 40/160 reads (25%) | catalogued as COSV62712813; called by muse, mutect2, varscan2
- GPALPP1 | c.252T>C p.D84= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as rs985122766; called by muse, mutect2, varscan2
- GSTM4 | c.528C>T p.D176= | Silent (SNP) | VAF 93/344 reads (27%) | catalogued as rs781512791; called by muse, mutect2, varscan2
- HCN1 | c.207C>T p.G69= | Silent (SNP) | VAF 80/286 reads (28%) | catalogued as rs1481532194, COSV57541098; called by mutect2, varscan2
- HMG20B | c.741G>A p.A247= | Silent (SNP) | VAF 67/234 reads (29%) | catalogued as COSV99503091; called by muse, mutect2, varscan2
- HMX1 | c.93C>T p.G31= | Silent (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- HNRNPL | c.276C>T p.Y92= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs145915975; called by muse, mutect2, varscan2
- INTS3 | c.1029G>A p.Q343= | Silent (SNP) | VAF 39/153 reads (25%) | catalogued as rs1331139430; called by muse, mutect2, varscan2
- ITSN2 | c.5037C>T p.T1679= | Silent (SNP) | VAF 44/145 reads (30%) | catalogued as rs767753085; called by muse, mutect2, varscan2
- JMY | c.1416G>A p.A472= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs373926091; called by muse, mutect2, varscan2
- KAT14 | c.2127A>G p.E709= | Silent (SNP) | VAF 38/121 reads (31%) | called by muse, mutect2, varscan2
- KCNJ3 | c.30C>T p.D10= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as COSV54539401, COSV99715328; called by muse, mutect2, varscan2
- KCNS1 | c.714C>T p.C238= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs1263685886; called by muse, mutect2, varscan2
- KIF3C | c.1383G>A p.L461= | Silent (SNP) | VAF 79/216 reads (37%) | catalogued as rs777125221; called by muse, mutect2, varscan2
- KRTAP20-3 | c.66C>A p.T22= | Silent (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- LAMB4 | c.5229T>C p.V1743= | Silent (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- LCT | c.3843G>A p.P1281= | Silent (SNP) | VAF 53/187 reads (28%) | catalogued as rs1265181323, COSV51556186; called by muse, mutect2, varscan2
- LGI2 | c.1005C>T p.D335= | Silent (SNP) | VAF 62/185 reads (34%) | catalogued as rs770238612, COSV101180773; called by muse, mutect2, varscan2
- LMTK3 | c.3948C>T p.S1316= | Silent (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- LRFN2 | c.1842C>T p.S614= | Silent (SNP) | VAF 54/161 reads (34%) | called by muse, mutect2, varscan2
- LRP4 | c.3954C>T p.G1318= | Silent (SNP) | VAF 97/340 reads (29%) | catalogued as rs1424152195, COSV66138569; called by muse, mutect2, varscan2
- LRRFIP1 | c.1065T>C p.T355= (on ENST00000392000 / NM_001137552.2; = p.T331= on NM_004735.4) | Silent (SNP) | VAF 30/113 reads (27%) | called by muse, mutect2, varscan2
- LUZP1 | c.2682T>G p.P894= | Silent (SNP) | VAF 66/222 reads (30%) | called by muse, mutect2, varscan2
- MAGEH1 | c.147C>T p.S49= | Silent (SNP) | VAF 34/121 reads (28%) | called by muse, mutect2, varscan2
- MAN1C1 | c.264G>A p.A88= | Silent (SNP) | VAF 55/152 reads (36%) | called by muse, mutect2, varscan2
- MAPK8IP1 | c.435C>T p.G145= | Silent (SNP) | VAF 23/263 reads (9%) | catalogued as rs1240447607; called by muse, mutect2, varscan2
- MARCHF6 | c.1785C>T p.N595= | Silent (SNP) | VAF 42/204 reads (21%) | catalogued as rs984884445; called by muse, mutect2, varscan2
- MICAL3 | c.1719A>G p.Q573= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as rs1462500855; called by muse, mutect2
- MIER3 | c.30C>T p.S10= | Silent (SNP) | VAF 56/190 reads (29%) | catalogued as rs780424566; called by muse, mutect2, varscan2
- MLLT6 | c.1305T>C p.S435= | Silent (SNP) | VAF 67/239 reads (28%) | called by muse, mutect2, varscan2
- MTFR1 | c.357C>A p.S119= | Silent (SNP) | VAF 70/258 reads (27%) | called by muse, mutect2, varscan2
- MVB12B | c.600A>G p.S200= | Silent (SNP) | VAF 54/176 reads (31%) | called by muse, mutect2, varscan2
- MYO7B | c.1533C>T p.D511= | Silent (SNP) | VAF 53/156 reads (34%) | catalogued as rs549700121, COSV101268400; called by muse, mutect2, varscan2
- NCOR2 | c.2610C>T p.A870= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs544420996; called by muse, mutect2, varscan2
- NDST2 | c.1299G>A p.S433= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as rs1476429369, COSV100013850; called by muse, mutect2, varscan2
- NKX6-2 | c.177C>T p.G59= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as rs1191064258; called by muse, mutect2, varscan2
- NLRP5 | c.1044G>A p.T348= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as rs762350545, COSV66764839; called by muse, mutect2, varscan2
- NOSIP | c.408C>T p.G136= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- NOXRED1 | c.600C>T p.S200= | Silent (SNP) | VAF 76/271 reads (28%) | catalogued as rs1323983456, COSV53628487; called by muse, mutect2, varscan2
- NRK | c.4218T>C p.L1406= | Silent (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- NSG1 | c.418C>A p.R140= | Silent (SNP) | VAF 92/333 reads (28%) | catalogued as COSV60373950; called by muse, mutect2, varscan2
- NTN1 | c.768G>A p.T256= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as rs1401307559; called by muse, mutect2, varscan2
- OLFML2B | c.2118A>G p.T706= | Silent (SNP) | VAF 68/315 reads (22%) | catalogued as rs1446345311; called by muse, mutect2, varscan2
- OSBP | c.2373C>T p.Y791= | Silent (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- PBX3 | c.1233C>T p.D411= | Silent (SNP) | VAF 56/179 reads (31%) | catalogued as rs769012950, COSV60730792; called by muse, mutect2, varscan2
- PDCD11 | c.4083G>A p.P1361= | Silent (SNP) | VAF 69/227 reads (30%) | catalogued as rs1324890608, COSV63933640; called by muse, mutect2, varscan2
- PEX11G | c.324C>T p.H108= | Silent (SNP) | VAF 41/140 reads (29%) | catalogued as rs757968202; called by muse, mutect2, varscan2
- PIK3CD | c.1101G>A p.S367= | Silent (SNP) | VAF 61/700 reads (9%) | catalogued as rs750134067, COSV63130799; called by muse, mutect2
- PLEC | c.11100A>G p.T3700= (on ENST00000322810 / NM_201380.4; = p.T3590= on NM_000445.5) | Silent (SNP) | VAF 191/669 reads (29%) | called by muse, mutect2, varscan2
- PLEKHH3 | c.1401C>T p.D467= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs375987832; called by muse, mutect2, varscan2
- PLXNB3 | c.4561C>T p.L1521= | Silent (SNP) | VAF 55/207 reads (27%) | called by muse, mutect2, varscan2
- POLE2 | c.1425C>T p.P475= | Silent (SNP) | VAF 31/135 reads (23%) | catalogued as rs776247497; called by muse, mutect2, varscan2
- POMGNT1 | c.1428C>T p.D476= | Silent (SNP) | VAF 156/515 reads (30%) | called by muse, mutect2, varscan2
- PPIL2 | c.327G>A p.V109= | Silent (SNP) | VAF 38/159 reads (24%) | catalogued as rs1356004994; called by muse, mutect2, varscan2
- PPP1R12C | c.693G>A p.L231= | Silent (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- PRDM11 | c.633C>T p.D211= (on ENST00000530656 / NM_001359633.1; = p.D177= on NM_001256695.1) | Silent (SNP) | VAF 62/247 reads (25%) | catalogued as rs139321801, COSV99770546; called by muse, mutect2, varscan2
- PRKAG3 | c.666C>T p.N222= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs200735141, COSV52101464; called by muse, mutect2, varscan2
- PRMT1 | c.1101C>T p.D367= | Silent (SNP) | VAF 83/283 reads (29%) | called by muse, mutect2, varscan2
- PTGDR | c.513C>T p.F171= | Silent (SNP) | VAF 91/290 reads (31%) | catalogued as rs756599455, COSV60094518; called by muse, mutect2, varscan2
- PTGER1 | c.1185G>A p.R395= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs891459499; called by muse, mutect2, varscan2
- REG3A | c.339C>T p.T113= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs143057391; called by muse, mutect2, varscan2
- RNF213 | c.5352G>A p.Q1784= | Silent (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- RPA4 | c.465C>T p.T155= | Silent (SNP) | VAF 74/211 reads (35%) | catalogued as rs761871309; called by muse, mutect2, varscan2
- RREB1 | c.4347G>A p.P1449= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as rs774014879; called by muse, mutect2, varscan2
- RTEL1 | c.1584G>A p.A528= | Silent (SNP) | VAF 45/157 reads (29%) | catalogued as rs568600515; called by muse, mutect2, varscan2
- RTL8B | c.162C>T p.D54= | Silent (SNP) | VAF 71/254 reads (28%) | called by muse, mutect2, varscan2
- SBNO2 | c.2244G>C p.A748= | Silent (SNP) | VAF 47/148 reads (32%) | called by muse, mutect2, varscan2
- SCN4A | c.138G>A p.E46= | Silent (SNP) | VAF 85/286 reads (30%) | called by muse, mutect2, varscan2
- SCN5A | c.2052A>G p.P684= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs761593528; called by muse, mutect2, varscan2
- SCRT2 | c.885C>T p.A295= | Silent (SNP) | VAF 32/112 reads (29%) | called by muse, mutect2
- SCUBE3 | c.2025T>C p.S675= | Silent (SNP) | VAF 26/112 reads (23%) | called by muse, mutect2, varscan2
- SKOR1 | c.1560A>G p.A520= | Silent (SNP) | VAF 51/168 reads (30%) | catalogued as COSV58248268; called by muse, mutect2, varscan2
- SLAIN1 | c.318G>A p.L106= (on ENST00000466548; = p.L128= on NM_001242868.2) | Silent (SNP) | VAF 48/170 reads (28%) | called by muse, mutect2, varscan2
- SLC7A9 | c.489G>A p.S163= | Silent (SNP) | VAF 73/248 reads (29%) | called by muse, mutect2, varscan2
- SOS1 | c.3255A>G p.T1085= | Silent (SNP) | VAF 76/252 reads (30%) | called by muse, mutect2, varscan2
- SPATA5L1 | c.1515G>C p.G505= | Silent (SNP) | VAF 105/302 reads (35%) | called by muse, mutect2, varscan2
- SSC5D | c.2487T>C p.P829= | Silent (SNP) | VAF 91/298 reads (31%) | called by muse, mutect2, varscan2
- STXBP5 | c.3267C>T p.G1089= (on ENST00000321680 / NM_001127715.2; = p.G1053= on NM_139244.4) | Silent (SNP) | VAF 90/353 reads (25%) | catalogued as rs775791413, COSV51649776; called by muse, mutect2, varscan2
- SYNPR | c.93C>T p.C31= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as rs376661036; called by muse, mutect2, varscan2
- TBC1D16 | c.1422C>T p.P474= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as COSV60479084; called by muse, mutect2, varscan2
- TBX4 | c.129G>A p.A43= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV53605463; called by muse, mutect2, varscan2
- TBXT | c.189C>T p.I63= | Silent (SNP) | VAF 92/309 reads (30%) | called by muse, mutect2, varscan2
149 further variants in this file (0 protein-altering or splice-affecting, 25 silent, 124 other) are not listed here.
